Surgical pathology report (de-identified scan), TCGA case TCGA-28-2499, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2499-01A (Primary Tumor).

CGA-28-2499

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

DIAGNOSIS:

A, B. BRAIN, LEFT PARIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

C. BRAIN, LEFT PARIETAL, CORE BIOPSY, NCI#1:

- Glioblastoma, WHO grade IV
- 95% of tumor cellularity
- Less than 2% of tumor necrosis

D. BRAIN, LEFT PARIETAL, CORE BIOPSY, NCI#2:

- Glioblastoma multiforme, WHO grade IV
- 95% of tumor cellularity
- Less than 5% of tumor necrosis

E. BRAIN, LEFT PARIETAL, CORE BIOPSY, NCI#3:

- Glioblastoma multiforme, WHO grade IV
- 95% of tumor cellularity
- 7% of tumor necrosis

F. BRAIN, LEFT PARIETAL, CORE BIOPSY, NCI#4:

- Glioblastoma multiforme, WHO grade IV
- 95% of tumor cellularity
- 12% of tumor necrosis

G. BRAIN, LEFT PARIETAL, CORE BIOPSY, NCI#5:

- Glioblastoma multiforme, WHO grade IV
- 95% of tumor cellularity
- 8% of tumor necrosis

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar [REDACTED]. Hence, the low 3% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Source: NCI Genomic Data Commons file 6069a1a1-18ab-4c58-a742-902912613a32 (TCGA-28-2499.5A1DD9DA-DF75-41B7-A37F-3005B4E1D7B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).